Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A439, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A439-01A (Primary Tumor).

Procurement Date: Laterality:Squamous cell carcinoma, Grade III, invading stromal tissue of cervix

Path Report:CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy

Tumor site: Cervix

Tumor size: 3 x 3 x 2.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Invasion beyond uterus

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: No pelvic extension; No lymph nodes examined; Corpus Involvement: Present

Comments: Non-keratinizing squamous cell carcinoma

Dual/Synchronous Primary	Noted	X

ICD-O-3

Carcinoma, Squamous cell, NOS
8070/3

Site: Cervix, NOS

C53.9 8-3-12 eo

Source: NCI Genomic Data Commons file dec403eb-e209-4ae3-bfb1-a965b4614a20 (TCGA-EA-A439.15BB85F2-5EF6-4569-B354-D543A0466983.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).